Gene-level copy-number profile of tumor specimen TCGA-56-7223-01A from TCGA case TCGA-56-7223, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.5 years (24,288 days).
Specimen TCGA-56-7223-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.10b63e76-a4ae-4a8f-afb2-0901a3364587.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-7223-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 832 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6999e99d-c3fd-4392-a321-2488834baa32

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,987; copy number 2: 21,815; copy number 3: 23,057; copy number 4: 9,822; copy number 5: 1,443; copy number 6: 229; copy number 7: 76; copy number 8: 196; copy number 9: 17; copy number 10: 3; copy number 11: 31; copy number 13: 50; copy number 14: 2; copy number 15: 3; copy number 17: 42; copy number 18: 8; copy number 19: 1; copy number 25: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-7223-01A-11D-2041-01): tumor purity 0.94, ploidy 2.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 436 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:209,827,972–210,171,389, 3 genes, copy number 7: UTP25, SYT14, AL022397.1.
- chr2:2,870,558–3,157,797, 4 genes, copy number 7: AC011995.1, LINC01250, AC019118.2, AC019118.1.
- chr2:16,224,047–16,974,497, 11 genes, copy number 7: AC010745.2, AC010745.3, AC010745.5, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA, AC008164.1, AC008069.1, LINC01866.
- chr2:81,461,358–81,666,728, 3 genes, copy number 7: LINC01815, RNA5SP99, AC013262.1.
- chr3:89,107,621–90,261,708, 8 genes, copy number 7 (within-gene range 2–7): EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr3:154,969,283–155,309,807, 7 genes, copy number 18: AC073359.1, MME, MME-AS1, LINC01487, STRIT1, AC104831.1, PABPC1P10.
- chr3:155,375,683–155,375,790, 1 gene, copy number 18: AC108729.3.
- chr3:160,696,929–160,755,142, 2 genes, copy number 7: SNORA72, AC069224.1.
- chr3:174,377,244–175,810,548, 5 genes, copy number 7–14 (within-gene range 4–14): AC069218.1, NAALADL2, RN7SKP40, EEF1B2P8, NAALADL2-AS3.
- chr3:175,675,087–175,941,037, 5 genes, copy number 8–11: AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1.
- chr3:176,415,439–176,867,838, 1 gene, copy number 10 (within-gene range 4–10): LINC01208.
- chr3:176,763,233–176,817,001, 2 genes, copy number 10: RNA5SP147, LINC01209.
- chr3:178,272,932–180,037,053, 33 genes, copy number 7–11 (within-gene range 4–11): KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1, ZNF639, AC007823.1, MFN1, GNB4, AC007620.2, AC007620.3, AC007620.1, MTHFD2P7, ACTL6A, AC090425.3, AC090425.2, MRPL47, NDUFB5, AC090425.1, H3P13, USP13, PEX5L, AC007687.1, PEX5L-AS1, PEX5L-AS2.
- chr3:180,820,544–183,616,742, 55 genes, copy number 7–17: AC108734.2, FLYWCH1P1, FXR1, AC108734.1, DNAJC19, SOX2-OT, AC083904.1, RNU6-4P, FAUP2, AC068308.1, RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.2, AC012081.1, AC109131.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1, LAMP3, MCF2L2, B3GNT5, RNA5SP151, LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3, KLHL6, KLHL6-AS1, AC068769.1.
- chr3:190,165,417–190,716,399, 11 genes, copy number 7–15: RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4.
- chr3:191,952,349–197,467,105, 158 genes, copy number 7–25 (broad region; genes not listed).
- chr17:27,333,241–29,404,105, 127 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,381. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
